Somatic mutation profile of tumor specimen 0DWI19 from CCDI case PBCKPU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Meningioma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 8.7 years (3,186 days).
Specimen 0DWI19: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4ac568ee-1046-41ab-bba4-c2c60cba3de9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWHZ3 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9d9e2f84-2d34-49d7-b8b4-7d179dfd6c53

The open-access MAF lists 8 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Intron 2, Silent 1, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTCH1 | c.3159dup p.G1054Rfs*91 | Frame Shift Ins (INS) | VAF 228/742 reads (31%) | catalogued as COSV59486527; called by mutect2, varscan2
- ADORA3 | c.283C>T p.H95Y | Missense Mutation (SNP) | VAF 207/748 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); called by muse, mutect2, varscan2
- MUC16 | c.21619A>G p.K7207E | Missense Mutation (SNP) | VAF 24/399 reads (6%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.031); called by muse, mutect2
- SIK2 | c.847T>C p.Y283H | Missense Mutation (SNP) | VAF 203/785 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CARD11 | c.2802G>A p.S934= | Silent (SNP) | VAF 138/622 reads (22%) | catalogued as rs139525282; ClinVar: likely benign; called by muse, mutect2, varscan2
- COMP | c.1136-76C>G | Intron (SNP) | VAF 6/100 reads (6%) | catalogued as rs866516146; called by muse, mutect2
- HERC1 | c.13689-48A>T | Intron (SNP) | VAF 5/91 reads (5%) | called by muse, mutect2
- MUC19 | n.6737A>G | RNA (SNP) | VAF 109/372 reads (29%) | called by muse, mutect2, varscan2
